Somatic mutation profile of tumor specimen BA2839D (aliquot aq-BA2839D) from BEATAML1.0 case 2107, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with myelodysplasia-related changes; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.3 years (16,196 days).
Specimen BA2839D: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c2c7f2b-0b4d-4bd3-853c-d08c43e0df8b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2393D (Solid Tissue Normal), aliquot aq-BA2393D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5bc26380-1323-442f-b89f-2f95ea2a4a0b

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'UTR 2, RNA 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2203G>A p.A735T | Missense Mutation (SNP) | VAF 104/229 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.253); catalogued as COSV57360335; called by muse, mutect2, varscan2
- TAS1R2 | c.2000G>A p.R667H | Missense Mutation (SNP) | VAF 18/224 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.175); catalogued as rs1262448574, COSV64743435; called by muse, mutect2
- APLP2 | c.897C>A p.D299E | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- TMEM175 | c.407del p.V136Gfs*12 | Frame Shift Del (DEL) | VAF 44/131 reads (34%) | called by mutect2, pindel, varscan2
- MKRN3 | c.*22G>A | 3'UTR (SNP) | VAF 49/132 reads (37%) | catalogued as rs528702082; called by muse, mutect2, varscan2
- TMEM183B | n.163G>T | RNA (SNP) | VAF 51/105 reads (49%) | called by muse, mutect2, varscan2
- TREM2 | c.*160G>T | 3'UTR (SNP) | VAF 3/27 reads (11%) | catalogued as COSV100632695; called by muse, mutect2
- ZNF761 | c.-12A>T | 5'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
